Somatic mutation profile of tumor specimen TCGA-DT-5265-01A (aliquot TCGA-DT-5265-01A-21D-1826-10) from TCGA case TCGA-DT-5265, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 51.1 years (18,669 days).
Specimen TCGA-DT-5265-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 317f002b-c898-42e6-a6e6-13fac0e0a5be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DT-5265-10A (Blood Derived Normal), aliquot TCGA-DT-5265-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dad44e69-d988-4959-a463-0a86427740b0

The open-access MAF lists 92 somatic variants for this specimen: 67 protein-altering or splice-affecting, 21 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 21, Nonsense Mutation 9, Frame Shift Ins 4, Intron 3, Splice Region 2, Frame Shift Del 2, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- ABCF3 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs748060492, COSV99490492; called by muse, mutect2, varscan2
- ADAMTS4 | c.1778G>A p.R593H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.125); catalogued as rs780697413, COSV63490428; called by muse, mutect2, varscan2
- ASTN1 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.541); catalogued as COSV56066712, COSV56075935; called by muse, mutect2, varscan2
- AVPR1A | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs1196990220, COSV54547261; called by muse, mutect2, varscan2
- BMPER | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV51823889; called by muse, mutect2, varscan2
- BRIP1 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 46/78 reads (59%) | catalogued as COSV52002871; called by muse, mutect2, varscan2
- BSX | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1379770999, COSV58005533; called by muse, mutect2, varscan2
- C6orf118 | c.840T>A p.S280R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57816697; called by muse, mutect2, varscan2
- CACNA2D3 | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 13/107 reads (12%) | catalogued as rs764015697, COSV55529480; called by muse, mutect2, varscan2
- CARMIL3 | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs758556019, COSV57727351; called by muse, mutect2
- CDKL2 | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs142919399, COSV100276844; called by mutect2, varscan2
- CHST10 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as rs367887748, COSV51804118; called by muse, mutect2, varscan2
- CNTN4 | c.2870C>T p.S957L | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as rs779923148, COSV100639471, COSV61868445; called by muse, mutect2, varscan2
- CNTNAP5 | c.2377G>A p.V793I | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs751028037, COSV70476456; called by muse, mutect2, varscan2
- COL4A3 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67417132; called by muse, mutect2, varscan2
- CYP2E1 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs187941410; called by muse, mutect2, varscan2
- DCDC1 | c.4156C>T p.R1386C (on ENST00000597505 / NM_001367979.1; = p.R493C on NM_020869.3) | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.555); catalogued as rs201587746, COSV58000770; called by muse, mutect2, varscan2
- DNHD1 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs772664290, COSV54437392; called by muse, mutect2, varscan2
- DOCK4 | c.2713C>T p.R905W | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs770258303, COSV70239925; called by muse, mutect2, varscan2
- DYNC2I1 | c.2318C>T p.T773M | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs866573617, COSV68105840; called by muse, mutect2, varscan2
- ERCC6L | c.3388G>A p.G1130R | Missense Mutation (SNP) | VAF 59/81 reads (73%) | SIFT tolerated (0.46); PolyPhen benign (0.034); catalogued as COSV57821446; called by muse, mutect2, varscan2
- FAM214A | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1169669477, COSV55925389; called by muse, mutect2, varscan2
- GMPS | c.1540A>G p.I514V | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.085); catalogued as rs761594481, COSV99903051; called by muse, mutect2, varscan2
- HERC4 | c.2870A>G p.E957G (on ENST00000395198 / NM_022079.3; = p.E949G on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as COSV53271124, COSV99516819; called by muse, mutect2, varscan2
- HSPG2 | c.201C>T p.D67= | Splice Region (SNP) | VAF 11/33 reads (33%) | catalogued as rs144919523; called by muse, mutect2, varscan2
- IKZF1 | c.588C>T p.S196= | Splice Region (SNP) | VAF 3/18 reads (17%) | catalogued as rs372403425, COSV58782412; called by muse, mutect2
- IQCN | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs757916869, COSV66573492; called by muse, mutect2, varscan2
- JAK3 | c.115dup p.Q39Pfs*13 | Frame Shift Ins (INS) | VAF 7/24 reads (29%) | catalogued as rs755706305; called by mutect2, varscan2
- JAKMIP1 | c.2239G>A p.G747S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs774733621, COSV68954159; called by muse, mutect2, varscan2
- LIMK2 | c.16+1G>T p.X6_splice | Splice Site (SNP) | VAF 17/35 reads (49%) | catalogued as COSV59183268; called by muse, mutect2, varscan2
- LRFN5 | c.2000del p.N667Tfs*12 | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | catalogued as COSV53255478; called by mutect2, pindel, varscan2
- LRRC7 | c.3752C>A p.S1251Y (on ENST00000651989 / NM_001370785.2; = p.S1218Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50509812; called by muse, mutect2, varscan2
- MACIR | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV60635396; called by muse, mutect2, varscan2
- MAP3K6 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.021); catalogued as COSV54641860; called by muse, mutect2, varscan2
- MRPL54 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs143484211; called by muse, mutect2, varscan2
- NCBP1 | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 18/75 reads (24%) | catalogued as COSV64317069; called by muse, mutect2, varscan2
- OR7C1 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as rs772802995, COSV50183672; called by muse, mutect2, varscan2
- PCDH15 | c.1320G>C p.E440D | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.602); catalogued as COSV57265857, COSV57347618; called by muse, mutect2, varscan2
- PDE4DIP | c.3152G>T p.S1051I | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57708897; called by muse, mutect2, varscan2
- PKP2 | c.651C>A p.Y217* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as CD119141, COSV50733095, COSV50736372; called by muse, mutect2, varscan2
- PM20D1 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as rs964719324, COSV65649157; called by muse, mutect2
- POT1 | c.1675C>T p.L559F | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62932211; called by muse, mutect2, varscan2
- POTEH | c.149A>G p.D50G | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.505); catalogued as rs776758594, COSV100624877; called by muse, varscan2
- PTPRM | c.2453C>G p.S818C | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.615); catalogued as COSV59869501; called by muse, varscan2
- PXDN | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs758869617, COSV53226263; called by muse, mutect2, varscan2
- SALL3 | c.3034C>T p.R1012* | Nonsense Mutation (SNP) | VAF 18/32 reads (56%) | catalogued as rs751879304, COSV101609972; called by muse, varscan2
- SDK1 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754503468, COSV67378325; called by muse, mutect2, varscan2
- SFRP4 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs775432602, COSV71412432; called by muse, varscan2
- SHANK1 | c.5359G>A p.V1787I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.007); catalogued as rs752168930, COSV53255766; called by muse, mutect2, varscan2
- SLC15A2 | c.145A>G p.I49V | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV55199098; called by muse, mutect2, varscan2
- SLC17A4 | c.11G>C p.G4A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100930548; called by muse, mutect2, varscan2
- SLC30A10 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV63072907; called by muse, mutect2
- SP1 | c.256C>T p.Q86* (on ENST00000327443 / NM_138473.3; = p.Q79* on NM_003109.1) | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100540511; called by muse, mutect2, varscan2
- SPEG | c.5807C>T p.P1936L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs1482633633, COSV56672459, COSV56674053; called by muse, mutect2, varscan2
- STAT5A | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372745237; called by muse, mutect2, varscan2
- TIAM1 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.193); catalogued as COSV54542288; called by muse, mutect2, varscan2
- TMEM248 | c.165G>A p.W55* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV58577859; called by muse, varscan2
- TMPRSS12 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1349206893, COSV68256764; called by muse, mutect2, varscan2
- TP53 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 16/31 reads (52%) | catalogued as CM044948, COSV52679410, COSV52730707, COSV52765316; called by muse, varscan2
- TP53BP1 | c.3458G>T p.G1153V | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99780257; called by muse, mutect2
- UGT3A2 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); catalogued as rs769005430, COSV56929023; called by muse, mutect2, varscan2
- ZFP91 | c.1514G>C p.G505A | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as COSV60160382; called by muse, mutect2, varscan2
- KIAA2026 | c.4389_4392dup p.I1465Cfs*28 | Frame Shift Ins (INS) | VAF 28/111 reads (25%) | called by mutect2, pindel, varscan2
- OR8B12 | c.205_223del p.D69Pfs*7 | Frame Shift Del (DEL) | VAF 7/79 reads (9%) | called by mutect2, pindel
- TROAP | c.753_754dup p.T252Rfs*37 | Frame Shift Ins (INS) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- AKNA | c.693G>C p.L231= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV99800079; called by muse, mutect2, varscan2
- ARSH | c.1098G>A p.P366= | Silent (SNP) | VAF 186/216 reads (86%) | catalogued as rs373570475, COSV66962780; called by muse, mutect2, varscan2
- CD163 | c.2544C>A p.G848= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV63134841; called by muse, mutect2, varscan2
- CPLX1 | c.357C>T p.T119= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs377036276, COSV58376711; called by muse, mutect2, varscan2
- DVL3 | c.1062G>T p.R354= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV57457128; called by muse, mutect2, varscan2
- ELOA2 | c.2073C>T p.S691= | Silent (SNP) | VAF 47/83 reads (57%) | catalogued as COSV55299089; called by muse, mutect2, varscan2
- FKBP10 | c.1386C>T p.H462= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as rs571808781, COSV54056659; called by muse, mutect2, varscan2
- GARNL3 | c.2487G>A p.P829= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs1292735935, COSV59228203; called by muse, mutect2, varscan2
- HNRNPDL | c.559A>C p.R187= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV55023063; called by muse, mutect2, varscan2
- KIF14 | c.4125C>A p.I1375= | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as COSV100950547, COSV66262599; called by muse, mutect2, varscan2
- LSR | c.447C>T p.L149= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV61555538; called by muse, mutect2, varscan2
- MARCHF1 | c.255C>T p.C85= (on ENST00000274056; = p.C68= on NM_017923.4) | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as rs776363990, COSV56812512, COSV56819636; called by muse, mutect2, varscan2
- NR4A3 | c.330G>A p.Q110= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100432313; called by muse, varscan2
- PAX3 | c.18C>T p.G6= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs1310695676, COSV51341589; called by muse, mutect2, varscan2
- SIPA1L2 | c.3396C>T p.P1132= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs1023173887, COSV53394230; called by muse, mutect2, varscan2
- SPTB | c.1500G>A p.T500= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs564067421, COSV101072040; called by muse, varscan2
- SUN5 | c.45C>T p.L15= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs768675300, COSV50063058; called by muse, mutect2, varscan2
- TNPO3 | c.1230G>A p.L410= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV55283985; called by muse, mutect2, varscan2
- TRIO | c.5001C>T p.F1667= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV60087806; called by muse, mutect2, varscan2
- TRMO | c.1035C>T p.A345= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs770775804, COSV64292309; called by muse, mutect2, varscan2
- ZBTB32 | c.810C>T p.P270= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV52891403; called by muse, mutect2, varscan2
- ACSL5 | c.-141T>A | 5'UTR (SNP) | VAF 6/27 reads (22%) | catalogued as COSV61132053; called by muse, mutect2, varscan2
- ATAD3B | c.325-10C>T | Intron (SNP) | VAF 36/105 reads (34%) | catalogued as rs1205957671, COSV58021987; called by muse, mutect2, varscan2
- CYHR1 | c.246+298C>T | Intron (SNP) | VAF 15/34 reads (44%) | catalogued as rs543509475, COSV56761975; called by muse, mutect2, varscan2
- PRKAA1 | c.363+466C>T | Intron (SNP) | VAF 10/58 reads (17%) | catalogued as COSV57185142; called by muse, mutect2, varscan2
